TCGA case TCGA-2Z-A9J7 — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d66c9261-6c0c-44b0-92fa-a43757f34cb2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 63 years; Vital status: Dead; Days to death: 139 days.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 63.6 years (23,230 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M1; AJCC clinical stage: Stage IV; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 103 days; Days to treatment end: 105 days; Treatment dose: 2,000 cGy; Number of fractions: 5; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 103 days; Days to treatment end: 115 days; Treatment dose: 3,000 cGy; Number of fractions: 5; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 116 days; Days to treatment end: 130 days; Treatment dose: 3,000 cGy; Number of fractions: 6; Treatment anatomic sites: Distant Site.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 63.9 years (23,326 days); Days to diagnosis: 96 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Day 96 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 139 days; Disease response: With Tumor.
- ECOG performance status: 3; Timepoint: Other.

Molecular and laboratory tests
- Leukocytes: Normal.
- Platelets: Elevated.
- Calcium: Normal.
- Hemoglobin: Low.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 55.7 kg; Height: 167.6 cm; BMI: 19.8.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 25; Tobacco smoking onset year: 1984; Tobacco smoking quit year: 2005.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2Z-A9J7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 90 mg.
  Slide TCGA-2Z-A9J7-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 3; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-2Z-A9J7-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2Z-A9J7-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: No; Tobacco smoking history indicator: 4; Treatment outcome first course: Progressive Disease; New tumor event diagnosis indicator: Yes.
- New tumor event, Locoregional procedure: New tumor event surgery: No.
- New tumor event, Metastatic procedure: New tumor event surgery met: No.
- New tumor event: New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 139 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 139 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 96 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2Z-A9J7-01A-11D-A381-01): tumor purity 0.94, ploidy 2.19, whole-genome doublings 0.
